Gene-level copy-number profile of tumor specimen TCGA-FB-AAPQ-01A from TCGA case TCGA-FB-AAPQ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.9 years (24,078 days).
Specimen TCGA-FB-AAPQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.ce3930d4-9bb4-4f0f-90f1-34da2395a450.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FB-AAPQ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/099996d2-62c3-477c-8aa8-af5a5dde1ef5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 12,650; copy number 2: 44,056; copy number 3: 1,901; copy number 4: 194; copy number 5: 816; copy number 7: 96; copy number 8: 68.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FB-AAPQ-01A-11D-A40V-01): tumor purity 0.48, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:14,477,955–15,330,282, 32 genes (within-gene range 0–1): CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 980 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,502,219–161,379,358, 324 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr6:8,102,711–8,343,139, 1 gene, copy number 5 (within-gene range 1–5): AL355499.1.
- chr6:8,341,937–8,435,561, 2 genes, copy number 5: AL359378.1, SLC35B3.
- chr6:9,596,110–11,862,970, 54 genes, copy number 5: OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B, AL357518.1, Metazoa_SRP, AL022724.1, ADTRP, AL022724.3, AL022724.2, AMD1P4.
- chr6:15,243,923–31,817,946, 599 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,270. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
